CCDI case PBCPHP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f4e10b2e-c07d-4b60-ade3-0e59272bb34f

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.5 years (1,652 days).

Biospecimens (2 samples)
- Samples 0DX0QD, 0DX0QY (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
